Somatic mutation profile of tumor specimen ALCH-B2R2-TTP1-A (aliquot ALCH-B2R2-TTP1-A-2-0-D-A78Q-36) from ALCHEMIST case ALCH-B2R2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,250 days).
Specimen ALCH-B2R2-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5bd8fe0-9323-46df-8309-253c7d7b9703.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2R2-NB1-A (Blood Derived Normal), aliquot ALCH-B2R2-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f34680ea-d9a8-49b3-ad8a-0afad1d19914

The open-access MAF lists 90 somatic variants for this specimen: 53 protein-altering or splice-affecting, 19 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 19, Intron 8, Nonsense Mutation 6, RNA 4, 3'UTR 3, 5'Flank 3, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.3764C>A p.S1255* | Nonsense Mutation (SNP) | VAF 38/244 reads (16%) | catalogued as rs76649725, CM920186, CM980356, COSV50044366, COSV50049297; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 56/244 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.2098G>T p.V700F | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV51566510; called by muse, mutect2
- AIM2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.89); catalogued as COSV63698147; called by muse, mutect2, varscan2
- CCDC22 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs912598985, COSV66109639; called by muse, mutect2, varscan2
- CD14 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV57370722; called by muse, mutect2, varscan2
- CHMP2A | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs893544316; called by muse, mutect2, varscan2
- CRYZL1 | c.131A>T p.Q44L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV104391591; called by muse, mutect2, varscan2
- DLG2 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs757214411, COSV54645937; called by muse, mutect2, varscan2
- ERBB3 | c.2612C>T p.A871V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as rs1434533672; called by muse, varscan2
- ITPR3 | c.7751C>A p.T2584K | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65268274; called by muse, mutect2
- LMO1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV59958119; called by muse, mutect2, varscan2
- MUC5B | c.14771C>T p.S4924L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.283); catalogued as rs767870646, COSV71595867; called by muse, mutect2, varscan2
- NABP1 | c.43A>T p.K15* | Nonsense Mutation (SNP) | VAF 24/132 reads (18%) | catalogued as rs775417740; called by muse, mutect2, varscan2
- NECTIN1 | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 27/214 reads (13%) | catalogued as COSV50598344; called by muse, mutect2, varscan2
- NMD3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs776286017; called by muse, mutect2, varscan2
- PDE5A | c.1960G>T p.D654Y | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53346842; called by muse, mutect2, varscan2
- PGBD5 | c.1304C>T p.A435V (on ENST00000525115; = p.A504V on NM_001258311.2) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs1189651773; called by mutect2, varscan2
- POLR1B | c.2365G>C p.D789H | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.468); catalogued as COSV99637153; called by muse, mutect2, varscan2
- PSMC2 | c.442C>G p.Q148E | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV53007097; called by muse, mutect2, varscan2
- REN | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 10/156 reads (6%) | catalogued as COSV65818558; called by muse, mutect2
- AP2B1 | c.1254_1255insA p.R419Tfs*8 | Frame Shift Ins (INS) | VAF 23/157 reads (15%) | called by mutect2, pindel*, varscan2
- BDH2 | c.684A>G p.E228= | Splice Region (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- BRWD3 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CLK1 | c.1007A>T p.H336L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CMYA5 | c.6893C>A p.S2298* | Nonsense Mutation (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- DNAJC13 | c.6487C>G p.L2163V | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DSCC1 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- EGFR | c.3036T>G p.D1012E | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, varscan2
- ETV4 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.452); called by muse, varscan2
- EYS | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT2 | c.10311G>C p.E3437D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOXO3B | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- FZR1 | c.677C>A p.S226* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- GNL3 | c.989T>C p.V330A | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMOX1 | c.56A>C p.E19A | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NDST3 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- NEMF | c.2085G>T p.M695I | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2
- OPTN | c.-11G>C | Splice Region (SNP) | VAF 26/219 reads (12%) | called by muse, mutect2, varscan2
- OR6K6 | c.550G>A p.V184M (on ENST00000368144; = p.V160M on NM_001005184.1) | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- OR8A1 | c.655T>G p.F219V | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- OTUD6A | c.54G>C p.E18D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCDHA5 | c.1816C>T p.L606F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCDHB3 | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, varscan2
- PLCB1 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.873); called by muse, mutect2
- SPACA7 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- STAT6 | c.884T>A p.F295Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- STIMATE | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TFDP2 | c.1036G>C p.E346Q (on ENST00000489671 / NM_001178139.2; = p.E286Q on NM_006286.5) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TNFRSF10B | c.1284C>A p.F428L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TRPM3 | c.1255G>C p.E419Q (on ENST00000357533 / NM_001366142.2; = p.E264Q on NM_020952.6) | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.065); called by muse, mutect2
- ZER1 | c.472G>T p.V158F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF766 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ALX1 | c.12G>A p.L4= | Silent (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- ARHGDIB | c.534C>T p.F178= | Silent (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- CSMD2 | c.540C>T p.H180= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs140478946; called by muse, mutect2, varscan2
- DTX2 | c.123C>T p.F41= | Silent (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2, varscan2
- HPCA | c.555C>T p.C185= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- LRP12 | c.2538G>T p.L846= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV52629405; called by muse, mutect2, varscan2
- MIB2 | c.2658G>A p.R886= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- MYEOV | c.240C>T p.L80= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV58293414; called by muse, mutect2
- NUP210 | c.3624G>C p.L1208= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV54413928; called by muse, mutect2, varscan2
- PDIA5 | c.462C>T p.V154= | Silent (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- POLR1B | c.2166G>A p.V722= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs770267443, COSV54500162; called by muse, mutect2, varscan2
- PREX1 | c.1080G>A p.K360= | Silent (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- SDHD | c.297C>T p.L99= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as rs749657880; ClinVar: likely benign; called by muse, mutect2
- SERPINF1 | c.141C>T p.F47= | Silent (SNP) | VAF 22/86 reads (26%) | called by muse, varscan2
- SHISA6 | c.561C>T p.F187= | Silent (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2
- SLC7A9 | c.831G>C p.V277= | Silent (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- SLFN12L | c.1275C>T p.F425= (on ENST00000260908 / NM_001363830.1; = p.F443= on NM_001195790.1) | Silent (SNP) | VAF 23/281 reads (8%) | called by muse, mutect2
- SOX5 | c.1854G>A p.E618= | Silent (SNP) | VAF 18/127 reads (14%) | called by muse, mutect2, varscan2
- TACC3 | c.1560G>C p.L520= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- ALAS1 | c.1762+81C>T | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- DPPA3P2 | n.432C>A | RNA (SNP) | VAF 42/223 reads (19%) | called by muse, mutect2, varscan2
- ESRP1 | chr8:94639205 C>G | 5'Flank (SNP) | VAF 4/27 reads (15%) | called by muse, varscan2
- FAM90A20P | n.948C>T | RNA (SNP) | VAF 24/202 reads (12%) | catalogued as rs745963887; called by muse, mutect2, varscan2
- IFI16 | c.*7G>C | 3'UTR (SNP) | VAF 14/58 reads (24%) | called by muse, varscan2
- LINC00602 | n.628C>G | RNA (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- LRRK2 | c.3496+1593del | Intron (DEL) | VAF 20/125 reads (16%) | called by mutect2, pindel, varscan2
- MARCHF10 | c.383-2387G>A | Intron (SNP) | VAF 16/118 reads (14%) | catalogued as rs1236025051; called by muse, mutect2, varscan2
- MRPL49 | chr11:65122315 G>A | 5'Flank (SNP) | VAF 6/28 reads (21%) | catalogued as rs1157234921, COSV99588958; called by muse, mutect2, varscan2
- MUCL3 | c.946+298C>A | Intron (SNP) | VAF 36/297 reads (12%) | catalogued as COSV58516905, COSV58518099; called by muse, mutect2, varscan2
- PAK6 | c.-117-544G>A | Intron (SNP) | VAF 2/16 reads (13%) | called by muse, mutect2
- PNP | c.181+76A>G | Intron (SNP) | VAF 23/150 reads (15%) | catalogued as rs780013434; called by muse, mutect2, varscan2
- PSMC2 | c.422+35C>T | Intron (SNP) | VAF 18/106 reads (17%) | catalogued as rs914997186; called by muse, varscan2
- RRM2B | c.48+155C>T | Intron (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2
- STAG3L2 | n.843G>C | RNA (SNP) | VAF 33/338 reads (10%) | called by muse, mutect2, varscan2
- SYNE3 | c.*8671C>G | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- VAPB | c.*3348C>G | 3'UTR (SNP) | VAF 30/245 reads (12%) | called by muse, mutect2, varscan2
- Y_RNA | chr14:50083727 G>A | 5'Flank (SNP) | VAF 6/59 reads (10%) | called by mutect2, varscan2
